Somatic mutation profile of tumor specimen HCM-CSHL-0817-C22-01A (aliquot HCM-CSHL-0817-C22-01A-21D-A85L-36) from HCMI case HCM-CSHL-0817-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 75.3 years (27,513 days).
Specimen HCM-CSHL-0817-C22-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 380dc0be-6598-4220-b651-886061279e7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0817-C22-10A (Blood Derived Normal), aliquot HCM-CSHL-0817-C22-10A-01D-A85L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4e7c288-7793-4e42-9639-2a9213b0ad76

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 14, Nonsense Mutation 3, 5'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA9 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 112/844 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as rs765834807, COSV100253321; called by muse, mutect2, varscan2
- CUBN | c.7330C>T p.R2444* | Nonsense Mutation (SNP) | VAF 66/716 reads (9%) | catalogued as rs557208468; called by muse, mutect2
- DCAF5 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 82/1113 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.013); catalogued as rs150859516, COSV58459382; called by muse, mutect2
- EPHA2 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 222/884 reads (25%) | catalogued as COSV64452291; called by muse, mutect2, varscan2
- FAM53C | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 47/1416 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as rs151178605, COSV53513217; called by muse, mutect2
- HIBCH | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 155/847 reads (18%) | catalogued as rs1357291112; called by muse, mutect2, varscan2
- KCNK4 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 222/874 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs1486888231; called by muse, mutect2, varscan2
- NELL1 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 64/893 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54295908; called by muse, mutect2
- OR2C3 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 226/838 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV63576147; called by muse, mutect2, varscan2
- PPP2R1B | c.1378A>G p.M460V | Missense Mutation (SNP) | VAF 270/874 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs555421329; called by muse, mutect2, varscan2
- SUSD4 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 201/1092 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs906392405; called by muse, mutect2, varscan2
- TCF7L2 | c.85_87del p.E29del | In Frame Del (DEL) | VAF 83/830 reads (10%) | catalogued as rs754968616; called by pindel, varscan2
- ZNF296 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 102/1376 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs1021778200; called by muse, mutect2
- BCORL1 | c.2071C>A p.P691T | Missense Mutation (SNP) | VAF 274/1349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A3 | c.296C>G p.P99R | Missense Mutation (SNP) | VAF 206/720 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CYP17A1 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 92/934 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.957); called by muse, mutect2
- DMXL2 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 82/829 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- FAM166B | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 93/895 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- HERC6 | c.1363T>C p.S455P | Missense Mutation (SNP) | VAF 69/591 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- MAP3K2 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 52/519 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- NPR1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 193/1057 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITPNM1 | c.1586A>G p.Q529R | Missense Mutation (SNP) | VAF 405/1289 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PRAMEF18 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 114/743 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.048); called by muse, mutect2
- PRAMEF19 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 110/1894 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.046); called by muse, mutect2
- SETD1B | c.5338G>A p.G1780S | Missense Mutation (SNP) | VAF 177/768 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TRPC5OS | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 165/863 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TYR | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 317/1025 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC13C | c.4705A>G p.T1569A | Missense Mutation (SNP) | VAF 124/475 reads (26%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XKR4 | c.989G>C p.S330T | Missense Mutation (SNP) | VAF 92/920 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- ZNF775 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 42/1451 reads (3%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.56); called by muse, mutect2
- AKAP3 | c.552T>C p.S184= | Silent (SNP) | VAF 78/639 reads (12%) | called by muse, mutect2, varscan2
- ASIC4 | c.1026G>C p.L342= (on ENST00000347842 / NM_182847.3; = p.L361= on NM_018674.6) | Silent (SNP) | VAF 148/875 reads (17%) | catalogued as COSV61734189; called by muse, mutect2
- C1QB | c.132A>C p.T44= | Silent (SNP) | VAF 197/720 reads (27%) | called by muse, mutect2, varscan2
- CELA3A | c.456C>G p.P152= | Silent (SNP) | VAF 216/903 reads (24%) | called by muse, mutect2, varscan2
- FAM47A | c.829C>A p.R277= | Silent (SNP) | VAF 289/1222 reads (24%) | catalogued as COSV60499024; called by muse, mutect2, varscan2
- FGB | c.954A>G p.L318= | Silent (SNP) | VAF 71/690 reads (10%) | called by muse, mutect2, varscan2
- FRMD4A | c.2493G>A p.Q831= | Silent (SNP) | VAF 54/1085 reads (5%) | catalogued as rs371465388; called by muse, mutect2
- LRRC63 | c.225T>C p.L75= | Silent (SNP) | VAF 22/812 reads (3%) | called by muse, mutect2
- RHBDF1 | c.1980C>T p.L660= | Silent (SNP) | VAF 159/774 reads (21%) | catalogued as rs1019559193; called by muse, mutect2, varscan2
- SDC3 | c.69C>T p.A23= | Silent (SNP) | VAF 34/264 reads (13%) | called by muse, varscan2
- SEPTIN4 | c.1380C>T p.S460= | Silent (SNP) | VAF 190/906 reads (21%) | catalogued as rs149667618; called by muse, mutect2, varscan2
- SLC10A3 | c.102G>A p.L34= | Silent (SNP) | VAF 126/1894 reads (7%) | called by muse, mutect2
- TAF1L | c.2319T>C p.L773= | Silent (SNP) | VAF 90/959 reads (9%) | catalogued as rs1473466002; called by muse, mutect2
- TTN | c.8604C>T p.V2868= (on ENST00000591111; = p.V2822= on NM_003319.4) | Silent (SNP) | VAF 136/874 reads (16%) | catalogued as rs753733308, COSV60176747; called by muse, mutect2, varscan2
- AL132655.7 | n.53C>T | RNA (SNP) | VAF 243/1138 reads (21%) | catalogued as COSV100008251; called by muse, mutect2, varscan2
- BRINP1 | c.-193C>A | 5'UTR (SNP) | VAF 34/772 reads (4%) | called by muse, mutect2
